Somatic mutation profile of tumor specimen MMRF_1945_1_BM_CD138pos (aliquot MMRF_1945_1_BM_CD138pos_T1_KBS5U_L06453) from MMRF case MMRF_1945, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.2 years (16,151 days).
Specimen MMRF_1945_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57af76b1-3d20-4048-8be0-ef53b6ed2fc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1945_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1945_1_PB_Whole_C2_KBS5U_L06486; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7b46561-186c-4c38-8f23-b3ca075dae52

The open-access MAF lists 86 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 33, Missense Mutation 28, Silent 10, Intron 7, Splice Site 2, 5'UTR 2, Nonsense Mutation 1, 3'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 35/117 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 18/116 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CNTN2 | c.2914C>G p.P972A | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV59348479; called by muse, mutect2, varscan2
- EFCC1 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1372607336, COSV71401744; called by muse, mutect2, varscan2
- FAT4 | c.8116G>C p.D2706H | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.575); catalogued as rs138340854; called by muse, mutect2, varscan2
- FCSK | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs1479247310; called by muse, mutect2
- GDA | c.920+1G>A p.X307_splice | Splice Site (SNP) | VAF 36/62 reads (58%) | catalogued as rs771573154, COSV99429531; called by muse, varscan2
- IGHV2-70 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372581706; called by muse, varscan2
- LAMB3 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs139547896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.3154G>T p.G1052C | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs927201996, COSV67287615; called by muse, mutect2, varscan2
- NLRP7 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs746988595, COSV60175739; called by muse, mutect2, varscan2
- RYR1 | c.7303C>T p.R2435C | Missense Mutation (SNP) | VAF 72/110 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62096581; called by muse, mutect2, varscan2
- SF3A2 | c.1065_1085del p.A361_P367del | In Frame Del (DEL) | VAF 16/35 reads (46%) | catalogued as rs774451139; called by mutect2, varscan2
- SNTG2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs371971068; called by muse, mutect2
- SOGA3 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs1381861979, COSV64109152; called by muse, mutect2
- ABCB7 | c.2001G>T p.L667F (on ENST00000373394 / NM_001271696.3; = p.L668F on NM_004299.6) | Missense Mutation (SNP) | VAF 70/129 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK | c.2485G>A p.G829S | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARL1 | c.515+5G>T | Splice Region (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- CALCRL | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.91); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CALN1 | c.593C>T p.A198V (on ENST00000329008 / NM_001017440.3; = p.A240V on NM_031468.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL11A1 | c.3881G>T p.G1294V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83B | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GCN1 | c.4220G>C p.G1407A | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1A1 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA11 | c.1658A>C p.N553T | Missense Mutation (SNP) | VAF 142/316 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by mutect2, varscan2
- LMTK3 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPAR1 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- MICU2 | c.73A>C p.S25R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- OR2J3 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- SP140 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- TOP1 | c.2294T>C p.F765S | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TOX3 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- WDFY3 | c.4365+1G>A p.X1455_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- AGXT | c.1098C>T p.C366= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as rs781304998; called by muse, mutect2, varscan2
- FAM98B | c.927T>C p.N309= | Silent (SNP) | VAF 11/334 reads (3%) | called by muse, mutect2
- IGHV2-70 | c.78T>G p.S26= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs370260778; called by muse, mutect2, varscan2
- IGLL5 | c.81G>A p.L27= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs56055217, COSV73249379; called by muse, mutect2, varscan2
- KCTD3 | c.711G>A p.K237= | Silent (SNP) | VAF 68/180 reads (38%) | catalogued as rs1246225561, COSV99379648; called by muse, mutect2, varscan2
- LRRC41 | c.235C>T p.L79= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs1356717475; called by muse, mutect2, varscan2
- SNAP91 | c.1617C>T p.A539= | Silent (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- SNTB1 | c.426C>T p.I142= | Silent (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- UNC79 | c.4062C>T p.N1354= (on ENST00000393151 / NM_001346218.2; = p.N1177= on NM_020818.5) | Silent (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- ZGRF1 | c.2577G>A p.T859= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs888018700; called by muse, mutect2
- ABAT | c.*1123G>A | 3'UTR (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- ADAMTS3 | c.862-30C>T | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- ANO3 | c.*1924G>A | 3'UTR (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- ATP11C | c.*1732T>A | 3'UTR (SNP) | VAF 33/102 reads (32%) | called by muse, mutect2, varscan2
- ATRX | c.*2507A>T | 3'UTR (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- BICC1 | c.*811G>A | 3'UTR (SNP) | VAF 26/56 reads (46%) | catalogued as rs1489083305; called by muse, mutect2, varscan2
- CRYZ | c.732+42G>T | Intron (SNP) | VAF 66/168 reads (39%) | called by muse, mutect2
- CYHR1 | c.*372G>A | 3'UTR (SNP) | VAF 51/111 reads (46%) | catalogued as rs766641354; called by muse, mutect2, varscan2
- CYTH1 | c.*446del | 3'UTR (DEL) | VAF 16/80 reads (20%) | catalogued as rs777290863; called by pindel, varscan2
- E2F2 | c.*1033C>T | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- EGR1 | c.-61G>A | 5'UTR (SNP) | VAF 22/52 reads (42%) | catalogued as COSV53517796; called by muse, mutect2, varscan2
- EYS | c.1766+3605del | Intron (DEL) | VAF 38/69 reads (55%) | catalogued as rs938328023; called by mutect2, varscan2
- GABRG3 | c.-248C>A | 5'UTR (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- GABRQ | c.*2931C>T | 3'UTR (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- GEM | c.*337dup | 3'UTR (INS) | VAF 36/85 reads (42%) | called by mutect2, pindel, varscan2
- GMEB2 | c.*785C>T | 3'UTR (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- GPD1L | c.*2686T>C | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- HIPK1 | c.*381C>T | 3'UTR (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- KCNB2 | c.*174A>G | 3'UTR (SNP) | VAF 29/70 reads (41%) | catalogued as rs1316128764; called by muse, mutect2, varscan2
- MED22 | c.*1660G>A | 3'UTR (SNP) | VAF 13/177 reads (7%) | catalogued as rs1189946229; called by muse, mutect2
- METTL2A | c.*3845G>A | 3'UTR (SNP) | VAF 80/198 reads (40%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*1225T>C | 3'UTR (SNP) | VAF 69/173 reads (40%) | called by muse, mutect2, varscan2
- MOK | c.693-257C>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- NHLRC1 | c.*327G>A | 3'UTR (SNP) | VAF 14/81 reads (17%) | catalogued as rs375143655; called by muse, mutect2, varscan2
- NSD1 | c.*1197G>A | 3'UTR (SNP) | VAF 56/179 reads (31%) | called by muse, mutect2, varscan2
- PAX6 | c.766-25C>T | Intron (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- PPAN | c.591-102A>G | Intron (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- PTEN | c.*1415T>G | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- RERG | c.*1058C>G | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- RFX3 | c.*929G>A | 3'UTR (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2, varscan2
- RNF144A | c.*3445A>T | 3'UTR (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- RTL8C | c.*554A>G | 3'UTR (SNP) | VAF 75/273 reads (27%) | called by muse, mutect2, varscan2
- RUNX3 | c.*1861C>T | 3'UTR (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- SCNN1A | c.-55+165G>A | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- SEMA3C | c.*2184C>A | 3'UTR (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*1003T>G | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- SPCS3 | c.*378A>G | 3'UTR (SNP) | VAF 38/97 reads (39%) | catalogued as rs1045236967; called by muse, mutect2, varscan2
- STXBP5 | chr6:147385573 G>T | 3'Flank (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- TENT5C | c.*3768G>A | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- TMEM132B | c.*6277G>T | 3'UTR (SNP) | VAF 54/99 reads (55%) | called by muse, mutect2, varscan2
- TNS4 | c.*1343C>A | 3'UTR (SNP) | VAF 14/28 reads (50%) | catalogued as rs951539035; called by muse, mutect2, varscan2
- VWA5A | c.*173C>T | 3'UTR (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- WSCD2 | c.*2046del | 3'UTR (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
